Gene-level copy-number profile of tumor specimen C3N-01025-04 from CPTAC case C3N-01025, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 52.9 years (19,325 days).
Specimen C3N-01025-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3c4c769f-3a49-4731-b491-e443c6af6746.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01025-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/9de1674b-0494-44a5-a019-fe7aa919dd29

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 71; copy number 1: 24,571; copy number 2: 24,541; copy number 3: 6,917; copy number 4: 2,575; copy number 5: 67; copy number 6: 24; copy number 7: 8; copy number 9: 71; copy number 10: 9; copy number 11: 7; copy number 15: 27; copy number 16: 20.

Homozygous deletions (total copy number 0; autosomes only): 70 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:51,662,693–52,711,148, 61 genes (within-gene range 0–1) (broad region; genes not listed).
- chr4:157,768,013–157,768,113, 1 gene: Y_RNA.
- chr5:174,045,706–174,243,501, 4 genes (within-gene range 0–1): NSG2, AC113423.1, AC113423.2, AC011333.1.
- chr21:13,038,160–13,120,807, 4 genes: ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 233 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,883,046–121,116,676, 64 genes, copy number 9 (within-gene range 2–9) (broad region; genes not listed).
- chr2:60,823,069–61,191,203, 17 genes, copy number 5 (within-gene range 4–5): LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P.
- chr4:53,377,641–55,798,731, 49 genes, copy number 5–16: FIP1L1, AC058822.1, LNX1, LNX1-AS1, AC095040.1, LNX1-AS2, AC124017.1, AC105384.1, AC105384.2, RPL21P44, AC110792.3, CHIC2, AC110792.2, AC110792.4, AC110792.1, MORF4L2P1, GSX2, RPL22P13, PDGFRA, LINC02283, AC098587.1, AC098868.1, LINC02260, KIT, AC097494.1, LINC02358, AC111194.1, RPL38P3, RNU6-410P, AC111194.2, RN7SL424P, KDR, RN7SL822P, AC021220.1, RNU6-746P, LRRC34P2, SRD5A3, FCF1P8, SRD5A3-AS1, AC069200.1, TMEM165, Y_RNA, CLOCK, Y_RNA, RN7SKP30, AC024243.1, PDCL2, NMU, RNU6-276P.
- chr6:72,522,641–75,206,053, 45 genes, copy number 5–7: FO393414.2, FO393414.1, FO393414.3, KCNQ5, MIR4282, KNOP1P4, PGAM1P10, KCNQ5-AS1, RBPMS2P1, KHDC1P1, AL365232.1, KHDC1L, KHDC1, AC019205.1, RPSAP41, EIF3EP1, SDCBP2P1, PAICSP3, DPPA5, KHDC3L, OOEP, OOEP-AS1, RPL39P3, RPS6P8, DDX43, CGAS, MTO1, RNU6-975P, RN7SL827P, EEF1A1, AL121972.1, AL603910.1, SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2, AL356473.1, COL12A1.
- chr11:68,754,620–68,844,410, 1 gene, copy number 7: CPT1A.
- chr11:69,641,156–71,252,577, 35 genes, copy number 10–15 (within-gene range 1–15): CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN, SHANK2, AP001271.1, AP001271.2, SHANK2-AS1, SHANK2-AS2, Y_RNA, AP000590.1, SHANK2-AS3.
- chr11:70,886,090–70,896,305, 1 gene, copy number 10: AP003783.1.
- chr19:19,997,058–20,321,305, 19 genes, copy number 9–16 (within-gene range 3–16): ZNF682, AC006539.2, AC006539.3, BNIP3P13, ZNF90, AC006539.1, AC011447.5, AC011447.3, AC011447.1, AC011447.2, BNIP3P15, ZNF486, BNIP3P16, AC011447.4, AC011447.6, AC011447.7, BNIP3P17, AC078899.3, AC078899.1.
- chr20:7,255,053–7,258,323, 1 gene, copy number 5: AL080248.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 6: FAM230E.

Autosomal genes at a single copy (total copy number 1): 21,744. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
